Gene-level copy-number profile of tumor specimen MP2PRT-PATGUY-TMP1-A from MP2PRT case MP2PRT-PATGUY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (668 days).
Specimen MP2PRT-PATGUY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6be3a277-e18b-41b6-9c87-cc262cc9cf24.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATGUY-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/8213a7ea-ddff-4c87-8a44-e8d2510ea6e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 264; copy number 1: 4,348; copy number 2: 54,225; copy number 3: 59.

Homozygous deletions (total copy number 0; autosomes only): 264 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,234,912, 37 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr2:89,947,512–90,235,370, 25 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr7:38,239,580–38,350,022, 19 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRGV5P, TRGV5.
- chr9:1,977,784–2,229,241, 5 genes: AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P.
- chr9:19,507,452–22,128,103, 71 genes (broad region; genes not listed).
- chr9:27,325,209–27,610,745, 7 genes: MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P.
- chr14:22,438,547–22,475,375, 10 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61.
- chr14:105,863,198–106,005,574, 45 genes (within-gene range 0–1): IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3.
- chr14:106,359,793–106,411,021, 9 genes (within-gene range 0–1): IGHV3-33, IGHVII-33-1, IGHV3-33-2, IGHV4-34, IGHV7-34-1, IGHV3-35, IGHV3-36, IGHV3-37, IGHV3-38.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr14:106,482,435–106,631,653, 25 genes (within-gene range 0–1): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47, IGHVIII-47-1, IGHV3-48, IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60.
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–1): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–1): IGHV3-64, IGHV3-65, IGHVII-65-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
